Somatic mutation profile of cancer-model specimen HCM-BROD-0208-C16-85B (3D Organoid, passage 6; aliquot HCM-BROD-0208-C16-85B-01D-A80U-36), derived from the primary tumor of HCMI case HCM-BROD-0208-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G3; Age at diagnosis: 71.2 years (26,023 days).
Specimen HCM-BROD-0208-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f2f84c5-d535-4868-a201-e8165f1d4ea0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0208-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0208-C16-10B-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/268868fc-1546-4218-8e03-deff077748d6

The open-access MAF lists 343 somatic variants for this specimen: 233 protein-altering or splice-affecting, 98 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 98, Nonsense Mutation 21, Intron 9, Frame Shift Del 6, In Frame Del 4, Frame Shift Ins 3, 5'UTR 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 145/298 reads (49%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 599/898 reads (67%) | catalogued as rs1057519283, COSV99385902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 174/175 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981671, CM993670, COSV64293729, COSV64297280; called by muse, mutect2, varscan2
- SNX14 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 96/180 reads (53%) | catalogued as rs760752847; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 391/393 reads (99%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH1C | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 134/472 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776511246, COSV50018869; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 129/398 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs745334846, COSV60620907, COSV60623160; called by muse, mutect2, varscan2
- ACACB | c.5842C>T p.R1948* | Nonsense Mutation (SNP) | VAF 93/338 reads (28%) | catalogued as rs554134867, COSV58127981; called by muse, mutect2, varscan2
- ACVR2A | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 293/295 reads (99%) | catalogued as COSV54018614; called by muse, mutect2, varscan2
- ADAMTS2 | c.2980G>A p.G994S | Missense Mutation (SNP) | VAF 223/423 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142429109; ClinVar: uncertain significance; called by muse, mutect2
- ADAMTS8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 159/475 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs775536904, COSV57291111; called by muse, mutect2, varscan2
- ADCK2 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 249/250 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs376247400; called by muse, mutect2, varscan2
- ADGRG6 | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 88/210 reads (42%) | catalogued as rs753135960; called by muse, mutect2, varscan2
- ALDH3B1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 262/858 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs755885207; called by muse, mutect2, varscan2
- AMDHD2 | c.1009G>A p.V337I (on ENST00000293971 / NM_001330449.2; = p.V367I on NM_015944.4) | Missense Mutation (SNP) | VAF 249/407 reads (61%) | SIFT tolerated (0.38); PolyPhen benign (0.067); catalogued as rs751231472; called by muse, mutect2, varscan2
- ANK1 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 193/384 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs572677389, COSV55896866; called by muse, mutect2, varscan2
- ANKRD53 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 591/592 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.318); catalogued as rs565609845, COSV55536905; called by muse, mutect2, varscan2
- AOPEP | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 49/471 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs761327668; called by muse, mutect2, varscan2
- ARHGEF10 | c.2210C>T p.A737V (on ENST00000398564; = p.A712V on NM_014629.4) | Missense Mutation (SNP) | VAF 423/423 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs201394769; called by muse, mutect2, varscan2
- ARVCF | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 374/376 reads (99%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as rs559742829, COSV54268356; called by muse, mutect2, varscan2
- ASAP3 | c.2506G>A p.G836R | Missense Mutation (SNP) | VAF 158/296 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs896085148, COSV100369456; called by muse, mutect2, varscan2
- ASH1L | c.8872C>T p.R2958C (on ENST00000368346 / NM_001366177.2; = p.R2953C on NM_018489.3) | Missense Mutation (SNP) | VAF 115/217 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1375751864, COSV64213624; called by muse, mutect2, varscan2
- ATN1 | c.2834G>A p.R945H | Missense Mutation (SNP) | VAF 261/405 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as rs781955511; called by muse, mutect2, varscan2
- AVPR1B | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 212/422 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV65637678; called by muse, mutect2, varscan2
- AXDND1 | c.2891A>T p.E964V | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62646684; called by muse, mutect2, varscan2
- B4GALNT4 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 182/528 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs374809392; called by muse, mutect2, varscan2
- BMP8B | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 141/338 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs150985572, COSV62928481; called by muse, mutect2
- CEP295NL | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 109/253 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.18); catalogued as rs536798002; called by muse, mutect2, varscan2
- CLEC18B | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 243/1088 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs745410335; called by muse, mutect2, varscan2
- CLUH | c.3854C>T p.A1285V (on ENST00000435359; = p.A1324V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 541/541 reads (100%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as rs775616460; called by muse, mutect2, varscan2
- CNTNAP4 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 123/437 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755378449; called by muse, mutect2, varscan2
- COL5A1 | c.2842C>T p.R948W | Missense Mutation (SNP) | VAF 449/629 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1030105888, COSV65665427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPB1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 294/295 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs760474959, COSV51571965; called by muse, mutect2, varscan2
- CROCC2 | c.3973G>A p.D1325N | Missense Mutation (SNP) | VAF 400/400 reads (100%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs915089733; called by muse, mutect2, varscan2
- CSMD3 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 262/510 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs373917048, COSV104398043; called by muse, mutect2, varscan2
- CSNK1G2 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 235/475 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.102); catalogued as rs760867567, COSV55336474; called by muse, mutect2, varscan2
- CSPG4 | c.5173G>A p.V1725M | Missense Mutation (SNP) | VAF 351/551 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs764884311; called by muse, mutect2, varscan2
- CTNND2 | c.3206G>A p.R1069H | Missense Mutation (SNP) | VAF 265/380 reads (70%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); catalogued as rs201174659, COSV58888665; called by muse, mutect2, varscan2
- CTRL | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 122/434 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1295381828; called by muse, mutect2, varscan2
- CYFIP2 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 164/320 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1478391225, COSV59035624; called by muse, mutect2, varscan2
- CYP4A11 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 158/315 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs1488482611; called by muse, mutect2, varscan2
- CYP4A22 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 66/544 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs375999051; called by muse, mutect2
- DAAM2 | c.2231G>A p.R744H | Missense Mutation (SNP) | VAF 228/229 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1481726587; called by muse, mutect2, varscan2
- DMTF1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 86/233 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs559006713, COSV58685724; called by muse, mutect2, varscan2
- DOC2A | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 355/574 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs758069645; called by muse, mutect2, varscan2
- DOCK4 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 359/360 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs1382037895, COSV70235406; called by muse, mutect2, varscan2
- DSE | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 162/323 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs148394823; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 144/254 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1442088241; called by muse, mutect2, varscan2
- ELFN1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 306/508 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1428412093, COSV70033877; called by muse, mutect2, varscan2
- EMILIN1 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 183/841 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs147976791; called by muse, mutect2, varscan2
- EPB42 | c.1006C>T p.R336W (on ENST00000441366 / NM_001114134.2; = p.R366W on NM_000119.3) | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201128283, COSV55749582; called by muse, mutect2, varscan2
- FAM120B | c.1990G>A p.V664I | Missense Mutation (SNP) | VAF 165/356 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.379); catalogued as rs140403171; called by muse, mutect2, varscan2
- FAM160B2 | c.2072C>T p.T691M | Missense Mutation (SNP) | VAF 277/279 reads (99%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs756173971; called by muse, mutect2, varscan2
- FAM47B | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 348/348 reads (100%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1270166173, COSV61452566; called by muse, mutect2, varscan2
- FBN2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 309/592 reads (52%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs368006487; called by muse, mutect2, varscan2
- FGD2 | c.1622C>T p.T541M | Missense Mutation (SNP) | VAF 156/317 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs145864024; called by muse, mutect2, varscan2
- FGD4 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 154/154 reads (100%) | catalogued as rs772352538; called by muse, mutect2, varscan2
- GPHB5 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 161/332 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.113); catalogued as rs776274107; called by muse, mutect2, varscan2
- GPR12 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 223/390 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs762826808, COSV67344942; called by muse, mutect2, varscan2
- GPR153 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 164/366 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs776741513, COSV100928439; called by muse, mutect2, varscan2
- GRIA1 | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 115/204 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs752447548, COSV53605030; ClinVar: not provided; called by muse, mutect2, varscan2
- GRM1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 188/387 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1267327740; called by muse, mutect2, varscan2
- GRM7 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 167/344 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as rs767400612, COSV63134452; called by muse, mutect2, varscan2
- H1-7 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 587/598 reads (98%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs550344470, COSV58602049; called by muse, mutect2, varscan2
- HDAC4 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs754027484, COSV61876006; called by muse, mutect2, varscan2
- HMCN1 | c.5065C>T p.R1689C | Missense Mutation (SNP) | VAF 165/335 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.906); catalogued as rs771562191, COSV54879633; called by muse, mutect2, varscan2
- IGF2R | c.4256C>T p.P1419L | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs1199631386, COSV63631792; called by muse, mutect2, varscan2
- IL1R2 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 218/220 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs776757109, COSV60206860; called by muse, mutect2, varscan2
- IL27RA | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 225/478 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs371858042; called by muse, mutect2, varscan2
- ITGA8 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100959235; called by muse, mutect2, varscan2
- ITGAL | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 130/396 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs1273830278; called by muse, mutect2, varscan2
- ITPRID2 | c.1376T>C p.I459T | Missense Mutation (SNP) | VAF 314/314 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs746385717; called by muse, mutect2, varscan2
- JAKMIP1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 225/453 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771019447; called by muse, mutect2, varscan2
- KALRN | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 455/457 reads (100%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.669); catalogued as COSV53762478, COSV53773546; called by muse, mutect2, varscan2
- KALRN | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 137/306 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1486661865, COSV53773122; called by muse, mutect2, varscan2
- KCNJ8 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 71/296 reads (24%) | catalogued as COSV99557552; called by muse, mutect2, varscan2
- KLF18 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 200/393 reads (51%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.991); catalogued as rs928466144; called by muse, mutect2, varscan2
- KLHL29 | c.2239G>A p.V747I | Missense Mutation (SNP) | VAF 164/690 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.793); catalogued as rs3795947; called by muse, mutect2, varscan2
- KLK6 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 227/644 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs372505913; called by muse, mutect2, varscan2
- KMT5C | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 224/700 reads (32%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs750483810; called by muse, mutect2, varscan2
- LDLR | c.2440C>T p.R814W | Missense Mutation (SNP) | VAF 186/409 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746616623, CM151110; called by muse, mutect2, varscan2
- LEMD1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 120/382 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs774547030, COSV65671111; called by muse, varscan2
- LRRC4B | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 220/645 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs774026348; called by muse, mutect2, varscan2
- LRSAM1 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 92/421 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs376468970; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MACF1 | c.21922C>T p.R7308C (on ENST00000372915; = p.R5353C on NM_012090.5) | Missense Mutation (SNP) | VAF 123/278 reads (44%) | catalogued as rs766386254; called by muse, mutect2, varscan2
- MAST1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 194/427 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs767761780; called by muse, mutect2, varscan2
- MBLAC1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 243/733 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934479206, COSV99498843; called by muse, mutect2, varscan2
- MC3R | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 832/834 reads (100%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs750661807; called by muse, mutect2, varscan2
- MCTP1 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 123/248 reads (50%) | catalogued as rs751396813, COSV56505812; called by muse, mutect2, varscan2
- MED12L | c.3307G>A p.V1103M | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765305359, COSV56380842; called by muse, mutect2, varscan2
- MED23 | c.3166C>T p.R1056* | Nonsense Mutation (SNP) | VAF 160/335 reads (48%) | catalogued as rs556616129; called by muse, mutect2, varscan2
- MEGF8 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 86/341 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs747511405, COSV52084678; called by muse, mutect2, varscan2
- METTL27 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 172/285 reads (60%) | catalogued as rs556800237; called by muse, mutect2, varscan2
- MIB1 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 291/291 reads (100%) | catalogued as rs769209279, COSV55090435, COSV99839391; called by muse, mutect2, varscan2
- MINDY4 | c.2140C>T p.R714W | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374963616; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 88/235 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs757922970, COSV54907073; called by muse, mutect2, varscan2
- MTNR1B | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 585/888 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs764087177, COSV57068015; called by muse, mutect2, varscan2
- MYO18B | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 166/358 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.121); catalogued as rs754871127, COSV59133711; called by muse, mutect2, varscan2
- MYO18B | c.5558C>T p.T1853M | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs758935335, COSV59142064; called by muse, mutect2, varscan2
- NEURL1 | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 289/515 reads (56%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs374768261; called by muse, mutect2, varscan2
- NLGN4X | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 321/322 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs763458960, COSV52016642, COSV52036801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 98/236 reads (42%) | catalogued as COSV69407880; called by mutect2, varscan2
- NRDE2 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 132/250 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748714522, COSV62963363; called by muse, mutect2, varscan2
- NRK | c.2045G>C p.R682P | Missense Mutation (SNP) | VAF 356/358 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV54607773; called by muse, mutect2, varscan2
- OPCML | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 224/394 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762120321, COSV59404700; called by muse, mutect2, varscan2
- OR14I1 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 168/478 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs761639634, COSV61200667; called by muse, mutect2, varscan2
- OR6K2 | c.940dup p.S314Ffs*9 | Frame Shift Ins (INS) | VAF 74/149 reads (50%) | catalogued as rs764050222; called by mutect2, varscan2
- PARD3 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 132/316 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs756201037; called by muse, mutect2, varscan2
- PATL1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 117/393 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs1414971163, COSV104411321; called by muse, mutect2, varscan2
- PCDH10 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 232/485 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV52094804; called by muse, mutect2, varscan2
- PCDHA12 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 223/464 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.253); catalogued as COSV56487703; called by muse, mutect2, varscan2
- PCDHB6 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 388/876 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV50694563; called by muse, mutect2
- PCDHGA5 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 167/397 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV54016968; called by muse, mutect2, varscan2
- PDE2A | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 175/503 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs770576443, COSV57807603; called by muse, mutect2, varscan2
- PDIA5 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 177/384 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763335058; called by muse, mutect2, varscan2
- PGGHG | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 300/464 reads (65%) | catalogued as rs143073034, COSV66887867; called by muse, mutect2, varscan2
- PHYHIP | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 274/581 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.646); catalogued as rs756175019, COSV58687915; called by muse, mutect2, varscan2
- PLCZ1 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770563339, COSV56850134; called by muse, mutect2, varscan2
- PLEKHA7 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 448/727 reads (62%) | SIFT tolerated (0.58); PolyPhen benign (0.041); catalogued as rs200595484; called by muse, mutect2, varscan2
- PLPP7 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 183/714 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs766904221; called by muse, mutect2, varscan2
- PPP3CC | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 312/314 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs777474578, COSV51499311; called by muse, mutect2, varscan2
- PRAMEF4 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 262/597 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs775644555, COSV52439564; called by muse, mutect2, varscan2
- PRR12 | c.413C>T p.A138V (on ENST00000615927; = p.A959V on NM_020719.3) | Missense Mutation (SNP) | VAF 594/894 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as rs371098369; called by muse, mutect2, varscan2
- PSMD13 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 118/437 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as rs751978043; called by muse, mutect2, varscan2
- PUS1 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 122/425 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs778147307; called by muse, mutect2, varscan2
- PZP | c.83+1G>A p.X28_splice | Splice Site (SNP) | VAF 147/147 reads (100%) | catalogued as rs202111005; called by muse, mutect2, varscan2
- RALGAPA2 | c.3215C>T p.P1072L | Missense Mutation (SNP) | VAF 130/458 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758314399, COSV52499435; called by muse, mutect2, varscan2
- RNF38 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 114/255 reads (45%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.433); catalogued as rs761694946; called by muse, mutect2, varscan2
- RPL14 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 218/435 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs148088669; called by muse, varscan2
- RPS6KA2 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 173/344 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV55829454; called by muse, mutect2, varscan2
- SART1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 111/317 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs764597455, COSV56710332; called by muse, mutect2, varscan2
- SEC14L4 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 232/483 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs757455217; called by muse, mutect2, varscan2
- SHANK1 | c.4252C>T p.R1418W | Missense Mutation (SNP) | VAF 274/873 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1457565686; called by muse, mutect2, varscan2
- SKOR1 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 710/1070 reads (66%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs745379221; called by muse, mutect2, varscan2
- SOD3 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 260/511 reads (51%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV66125428; called by muse, mutect2, varscan2
- SOS2 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 130/271 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV53568235; called by muse, mutect2, varscan2
- SOX1 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 76/134 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs1429367216; called by muse, varscan2
- SPTBN4 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 242/364 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759607695, COSV58944062; called by muse, mutect2, varscan2
- SPTBN4 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 300/869 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as rs1472566291; called by muse, mutect2, varscan2
- SYNE2 | c.16753C>T p.R5585C | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs370674900, COSV59946696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SZT2 | c.5516G>A p.R1839H (on ENST00000634258 / NM_001365999.1; = p.R1782H on NM_015284.4) | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs760427137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TANGO6 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 279/452 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs770819768; called by muse, mutect2, varscan2
- TLCD3B | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 173/537 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV54228498; called by muse, mutect2, varscan2
- TMCC1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 121/230 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.434); catalogued as rs138991323, COSV100260918; called by muse, mutect2, varscan2
- TMEM151A | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 334/997 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs1383246355, COSV59174913; called by muse, mutect2, varscan2
- TMPRSS7 | c.631C>T p.R211W (on ENST00000452346; = p.R98W on NM_001042575.2) | Missense Mutation (SNP) | VAF 174/338 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234927733; called by muse, mutect2, varscan2
- TNFAIP3 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 264/497 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as rs568826568; called by muse, mutect2, varscan2
- TNK1 | c.1937G>A p.R646H (on ENST00000576812 / NM_001251902.2; = p.R641H on NM_003985.5) | Missense Mutation (SNP) | VAF 354/356 reads (99%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs373049680; called by muse, mutect2, varscan2
- TRIM5 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 115/426 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760714681, COSV59902725; called by muse, mutect2, varscan2
- TRIM68 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 409/626 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760538270, COSV100331659, COSV56168250; called by muse, mutect2, varscan2
- TRPM7 | c.2704C>T p.R902C | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs770110235, COSV57921486; called by muse, mutect2, varscan2
- USP17L4 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 158/160 reads (99%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1322825500; called by muse, mutect2, varscan2
- VAMP8 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 166/392 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as rs759295495, COSV55705188; called by muse, mutect2, varscan2
- VGLL2 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 220/465 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.578); catalogued as COSV100409926, COSV58310699; called by muse, mutect2, varscan2
- VOPP1 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 166/264 reads (63%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs763651805; called by muse, mutect2, varscan2
- WNK2 | c.4406C>T p.T1469M (on ENST00000297954 / NM_001282394.1; = p.T1432M on NM_006648.3) | Missense Mutation (SNP) | VAF 189/793 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs373618412; called by muse, mutect2, varscan2
- ZAR1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 244/456 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs945477385; called by muse, varscan2
- ZNF425 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 163/513 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as rs1165656351, COSV65201205; called by muse, mutect2, varscan2
- ZNF521 | c.743G>T p.C248F | Missense Mutation (SNP) | VAF 218/400 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64123469; called by muse, mutect2, varscan2
- ZNF559 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 150/354 reads (42%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.912); catalogued as rs531973512, COSV57837752; called by muse, mutect2, varscan2
- AC011448.1 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 172/376 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- APOBEC3G | c.423_424del p.D143Rfs*12 | Frame Shift Del (DEL) | VAF 260/298 reads (87%) | called by mutect2, pindel, varscan2
- ASTN2 | c.3224C>A p.T1075K (on ENST00000313400 / NM_001365069.1; = p.T1024K on NM_014010.5) | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BAP1 | c.2038_2039dup p.M681Pfs*12 | Frame Shift Ins (INS) | VAF 205/278 reads (74%) | called by mutect2, pindel, varscan2
- BRD3 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 436/577 reads (76%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CACNA1F | c.4780C>T p.R1594C | Missense Mutation (SNP) | VAF 295/297 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASZ1 | c.5203G>A p.A1735T | Missense Mutation (SNP) | VAF 86/165 reads (52%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, varscan2
- CCDC180 | c.2476C>G p.L826V | Missense Mutation (SNP) | VAF 307/312 reads (98%) | SIFT tolerated (0.21); PolyPhen benign (0.14); called by muse, mutect2
- CCKAR | c.272_273del p.C91Sfs*40 | Frame Shift Del (DEL) | VAF 188/475 reads (40%) | called by mutect2, pindel, varscan2
- CDH18 | c.1571A>T p.N524I | Missense Mutation (SNP) | VAF 238/550 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CHD4 | c.1342del p.L448Cfs*16 (on ENST00000357008 / NM_001363606.2; = p.L461Cfs*16 on NM_001273.5) | Frame Shift Del (DEL) | VAF 120/454 reads (26%) | called by mutect2, pindel, varscan2
- CLIP2 | c.1009A>G p.S337G | Missense Mutation (SNP) | VAF 210/324 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CNTLN | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COG3 | c.1255C>G p.H419D | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DACT3 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 59/634 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- DAPK1 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 70/353 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DBX1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 176/726 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ERBB4 | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 222/223 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXC2 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 231/718 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FPGT | c.1528T>A p.F510I | Missense Mutation (SNP) | VAF 123/257 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GGT1 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 368/369 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GNAI3 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 60/135 reads (44%) | called by muse, mutect2, varscan2
- GPR150 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 287/649 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- HEPH | c.68G>T p.G23V (on ENST00000343002; = p.G77V on NM_138737.5) | Missense Mutation (SNP) | VAF 296/297 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- IRS4 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 356/356 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- IST1 | c.364C>T p.R122* (on ENST00000535424 / NM_001270976.1; = p.R109* on NM_014761.4) | Nonsense Mutation (SNP) | VAF 88/322 reads (27%) | called by muse, mutect2, varscan2
- IVL | c.1184A>T p.H395L | Missense Mutation (SNP) | VAF 263/532 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIF26B | c.2432G>T p.S811I | Missense Mutation (SNP) | VAF 206/631 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- KMO | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LHX2 | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 326/450 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- LMBRD2 | c.1284_1285del p.Y428* | Nonsense Mutation (DEL) | VAF 50/262 reads (19%) | called by pindel, varscan2
- MED12L | c.4510C>T p.R1504* | Nonsense Mutation (SNP) | VAF 213/216 reads (99%) | called by muse, mutect2, varscan2
- MESP2 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 210/1237 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by mutect2, varscan2
- MSX1 | c.787G>C p.V263L | Missense Mutation (SNP) | VAF 296/665 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYCBP2 | c.7291C>T p.R2431* (on ENST00000357337; = p.R2469* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 101/198 reads (51%) | called by muse, mutect2, varscan2
- NES | c.1489G>T p.G497C | Missense Mutation (SNP) | VAF 210/438 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NES | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 320/581 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- NLRP6 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 584/905 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, varscan2
- NRG1 | c.1832G>A p.R611K (on ENST00000405005 / NM_013964.5; = p.R616K on NM_013956.5) | Missense Mutation (SNP) | VAF 252/444 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NUMA1 | c.2440C>T p.R814C | Missense Mutation (SNP) | VAF 400/643 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- OPTN | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OR52D1 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 118/513 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLCXD3 | c.494T>G p.I165S | Missense Mutation (SNP) | VAF 405/594 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PLXNC1 | c.2418C>A p.C806* | Nonsense Mutation (SNP) | VAF 183/183 reads (100%) | called by muse, mutect2, varscan2
- PRRX2 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 568/693 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- PUM3 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 128/255 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- RERE | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 222/449 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SCN7A | c.1231A>T p.I411F | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SEPSECS | c.308_310del p.A103del | In Frame Del (DEL) | VAF 78/170 reads (46%) | called by pindel, varscan2
- SHH | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 235/726 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC30A1 | c.1029_1031del p.L344del | In Frame Del (DEL) | VAF 70/270 reads (26%) | called by pindel, varscan2
- SLC6A14 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 237/237 reads (100%) | called by muse, mutect2, varscan2
- SPEG | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 703/706 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SPTBN4 | c.1273_1275del p.E425del | In Frame Del (DEL) | VAF 242/431 reads (56%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.1073C>T p.S358L (on ENST00000621492; = p.S324L on NM_025248.3) | Missense Mutation (SNP) | VAF 672/675 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- STAB2 | c.6900G>T p.K2300N | Missense Mutation (SNP) | VAF 169/238 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- STARD9 | c.8728G>T p.G2910W | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TNPO2 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 165/372 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TOX2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- TRBJ2-7 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 107/434 reads (25%) | called by muse, mutect2, varscan2
- USP6NL | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 103/104 reads (99%) | called by muse, mutect2, varscan2
- WASF3 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 176/316 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WNT5B | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 304/413 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- XIRP2 | c.2488C>A p.Q830K (on ENST00000628543; = p.Q1005K on NM_152381.6) | Missense Mutation (SNP) | VAF 327/329 reads (99%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- XKR6 | c.602G>A p.S201N | Missense Mutation (SNP) | VAF 662/664 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ZC3H11B | c.2122C>T p.L708F | Missense Mutation (SNP) | VAF 147/903 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.087); called by muse, mutect2
- ZC3H13 | c.3991dup p.W1331Lfs*9 | Frame Shift Ins (INS) | VAF 188/510 reads (37%) | called by mutect2, pindel, varscan2
- ZNF263 | c.2003_2005del p.F668del | In Frame Del (DEL) | VAF 98/369 reads (27%) | called by mutect2, pindel, varscan2
- ZNF562 | c.431T>C p.M144T (on ENST00000453372 / NM_001130032.2; = p.M72T on NM_017656.4) | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- ZNF614 | c.180G>T p.L60F | Missense Mutation (SNP) | VAF 103/397 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- ZNF626 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF69 | c.527_533del p.H176Pfs*35 | Frame Shift Del (DEL) | VAF 65/213 reads (31%) | called by mutect2, pindel, varscan2
- ZNF79 | c.1113_1116del p.S371Rfs*34 | Frame Shift Del (DEL) | VAF 397/622 reads (64%) | called by mutect2, pindel, varscan2
- ACKR3 | c.72C>T p.S24= | Silent (SNP) | VAF 301/302 reads (100%) | catalogued as rs115338217; called by muse, mutect2, varscan2
- ACOT7 | c.354C>T p.I118= (on ENST00000377855 / NM_181864.3; = p.I108= on NM_007274.4) | Silent (SNP) | VAF 186/366 reads (51%) | catalogued as rs765693356, COSV64114888; called by muse, mutect2, varscan2
- ADGRV1 | c.16449C>T p.F5483= | Silent (SNP) | VAF 114/223 reads (51%) | catalogued as rs371911273; called by muse, mutect2, varscan2
- AJM1 | c.1974C>T p.D658= | Silent (SNP) | VAF 314/426 reads (74%) | catalogued as rs772733032, COSV56034297; called by muse, mutect2, varscan2
- ANK1 | c.2268C>T p.N756= | Silent (SNP) | VAF 209/209 reads (100%) | catalogued as rs759268149, COSV55899125; called by muse, mutect2, varscan2
- AP002748.5 | c.1254C>T p.Y418= | Silent (SNP) | VAF 124/435 reads (29%) | catalogued as rs1021331909; called by muse, mutect2, varscan2
- BARHL2 | c.915G>A p.S305= | Silent (SNP) | VAF 209/444 reads (47%) | catalogued as rs771489833, COSV64982074; called by muse, mutect2, varscan2
- BICRA | c.4011C>T p.P1337= | Silent (SNP) | VAF 555/797 reads (70%) | catalogued as rs1243717031; called by muse, mutect2, varscan2
- C15orf39 | c.2520C>T p.G840= | Silent (SNP) | VAF 270/803 reads (34%) | catalogued as rs748746702; called by muse, mutect2, varscan2
- C3 | c.819C>T p.F273= | Silent (SNP) | VAF 140/328 reads (43%) | catalogued as rs886054656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.2712C>T p.S904= | Silent (SNP) | VAF 68/258 reads (26%) | catalogued as rs549664833; called by muse, mutect2, varscan2
- CACNA1I | c.1560G>A p.S520= | Silent (SNP) | VAF 115/276 reads (42%) | catalogued as rs747079938, COSV60810214; called by muse, mutect2, varscan2
- CHAT | c.1308C>T p.C436= | Silent (SNP) | VAF 195/420 reads (46%) | catalogued as rs764875843, COSV60319893, COSV60332806; called by muse, mutect2, varscan2
- CHRNB2 | c.1110C>T p.R370= | Silent (SNP) | VAF 274/528 reads (52%) | catalogued as rs763983504, COSV63808591; called by muse, mutect2, varscan2
- CHST1 | c.627C>T p.R209= | Silent (SNP) | VAF 232/637 reads (36%) | called by muse, mutect2, varscan2
- CLTCL1 | c.2994C>T p.A998= | Silent (SNP) | VAF 158/331 reads (48%) | catalogued as rs1427214896; called by muse, mutect2, varscan2
- CPAMD8 | c.5727C>T p.F1909= (on ENST00000651564; = p.F1862= on NM_015692.5) | Silent (SNP) | VAF 202/361 reads (56%) | catalogued as rs750639642, COSV50186403; called by muse, mutect2, varscan2
- CPLANE1 | c.8049C>A p.V2683= | Silent (SNP) | VAF 161/623 reads (26%) | called by muse, mutect2, varscan2
- DACT3 | c.522G>A p.P174= | Silent (SNP) | VAF 62/412 reads (15%) | called by muse, mutect2, varscan2
- DDOST | c.1206G>T p.L402= (on ENST00000415136; = p.L385= on NM_005216.5) | Silent (SNP) | VAF 169/332 reads (51%) | called by muse, mutect2, varscan2
- DMRTA1 | c.423G>A p.A141= | Silent (SNP) | VAF 563/565 reads (100%) | catalogued as rs896875470; called by muse, mutect2, varscan2
- DMXL1 | c.1413G>A p.S471= | Silent (SNP) | VAF 139/288 reads (48%) | catalogued as rs768346418; called by muse, mutect2, varscan2
- DNAH5 | c.13383T>C p.L4461= | Silent (SNP) | VAF 230/573 reads (40%) | called by muse, mutect2, varscan2
- EIF2AK4 | c.4512C>T p.S1504= | Silent (SNP) | VAF 83/415 reads (20%) | catalogued as rs181699370; called by muse, mutect2, varscan2
- EIF3D | c.1026G>A p.P342= | Silent (SNP) | VAF 151/356 reads (42%) | catalogued as rs547158688; called by muse, mutect2, varscan2
- ESPL1 | c.5577C>T p.Y1859= | Silent (SNP) | VAF 78/370 reads (21%) | catalogued as rs527909578, COSV99229002; called by muse, varscan2
- ESPN | c.3387G>A p.A1129= | Silent (SNP) | VAF 361/702 reads (51%) | catalogued as rs1220083718; called by muse, mutect2, varscan2
- FAM86B1 | c.513C>A p.G171= | Silent (SNP) | VAF 254/1089 reads (23%) | called by muse, mutect2, varscan2
- FAM86B2 | c.615C>A p.G205= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as rs1449813963; called by muse, mutect2, varscan2
- FAN1 | c.2499C>T p.G833= | Silent (SNP) | VAF 102/484 reads (21%) | catalogued as rs374193799; called by muse, mutect2, varscan2
- FBLIM1 | c.903C>T p.P301= | Silent (SNP) | VAF 143/330 reads (43%) | catalogued as rs781317747, COSV60029626; called by muse, mutect2, varscan2
- FBN1 | c.1341A>T p.V447= | Silent (SNP) | VAF 96/207 reads (46%) | called by muse, mutect2, varscan2
- FGF4 | c.219C>T p.A73= | Silent (SNP) | VAF 579/852 reads (68%) | catalogued as rs777152596; called by muse, mutect2, varscan2
- FPGS | c.981G>A p.E327= | Silent (SNP) | VAF 153/655 reads (23%) | catalogued as rs924101941; called by muse, mutect2, varscan2
- GJA8 | c.201C>T p.D67= | Silent (SNP) | VAF 164/343 reads (48%) | catalogued as rs781782991, COSV53788040; called by muse, mutect2, varscan2
- GPA33 | c.360G>A p.S120= | Silent (SNP) | VAF 133/299 reads (44%) | catalogued as rs565383649, COSV100901018, COSV63300689; called by muse, mutect2, varscan2
- GRIN2D | c.3231C>T p.G1077= | Silent (SNP) | VAF 55/73 reads (75%) | called by muse, mutect2, varscan2
- HAUS6 | c.12C>G p.A4= | Silent (SNP) | VAF 79/190 reads (42%) | called by muse, mutect2, varscan2
- HS3ST6 | c.159G>A p.P53= | Silent (SNP) | VAF 84/200 reads (42%) | called by muse, varscan2
- IGDCC4 | c.2958C>T p.S986= | Silent (SNP) | VAF 124/451 reads (27%) | called by muse, mutect2, varscan2
- IGF1R | c.1371C>T p.S457= | Silent (SNP) | VAF 148/512 reads (29%) | catalogued as rs375300684; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHE | c.972G>A p.P324= | Silent (SNP) | VAF 24/796 reads (3%) | catalogued as rs782739922; called by muse, mutect2
- ISM2 | c.660C>T p.A220= | Silent (SNP) | VAF 288/291 reads (99%) | catalogued as rs777396047, COSV53633840; called by muse, mutect2, varscan2
- JAK3 | c.522G>A p.A174= | Silent (SNP) | VAF 228/490 reads (47%) | catalogued as rs761971689; called by muse, mutect2, varscan2
- KCND2 | c.1173G>A p.S391= | Silent (SNP) | VAF 156/395 reads (39%) | catalogued as rs367909110; called by muse, mutect2, varscan2
- KDM6A | c.2178G>A p.T726= | Silent (SNP) | VAF 342/343 reads (100%) | catalogued as rs772137452, COSV100938511, COSV100938543; called by muse, mutect2, varscan2
- LARS2 | c.762C>T p.D254= | Silent (SNP) | VAF 121/245 reads (49%) | catalogued as rs144694969; called by muse, mutect2, varscan2
- MARCHF11 | c.276C>T p.A92= | Silent (SNP) | VAF 543/742 reads (73%) | called by muse, mutect2, varscan2
- MGAM2 | c.4788G>A p.T1596= | Silent (SNP) | VAF 178/285 reads (62%) | catalogued as rs1243323293; called by muse, mutect2, varscan2
- MGP | c.246C>T p.Y82= | Silent (SNP) | VAF 355/355 reads (100%) | catalogued as rs145024683; called by muse, mutect2, varscan2
- MTTP | c.111G>A p.T37= | Silent (SNP) | VAF 156/337 reads (46%) | catalogued as rs147921439; called by muse, mutect2, varscan2
- MUC12 | c.13740A>G p.S4580= (on ENST00000379442; = p.S4437= on NM_001164462.1) | Silent (SNP) | VAF 224/3340 reads (7%) | called by muse, mutect2
- MYRFL | c.1290G>A p.A430= | Silent (SNP) | VAF 112/384 reads (29%) | catalogued as rs1246456924; called by muse, mutect2, varscan2
- NAA35 | c.1887G>A p.P629= | Silent (SNP) | VAF 108/440 reads (25%) | catalogued as rs774023757, COSV100863293; called by muse, mutect2, varscan2
- NAT16 | c.663C>T p.G221= | Silent (SNP) | VAF 528/530 reads (100%) | catalogued as COSV55864421; called by muse, mutect2, varscan2
- NEK9 | c.2274C>T p.G758= | Silent (SNP) | VAF 170/368 reads (46%) | catalogued as rs376937236; called by muse, varscan2
- NOP53 | c.477C>T p.G159= | Silent (SNP) | VAF 206/650 reads (32%) | catalogued as rs773436143; called by muse, mutect2, varscan2
- NOVA2 | c.702C>T p.P234= | Silent (SNP) | VAF 218/762 reads (29%) | catalogued as rs765148301; called by muse, mutect2, varscan2
- NR2E3 | c.672G>A p.S224= | Silent (SNP) | VAF 423/616 reads (69%) | catalogued as rs530684859, COSV100489550; called by muse, mutect2, varscan2
- OPN1SW | c.417C>A p.P139= | Silent (SNP) | VAF 100/376 reads (27%) | called by muse, mutect2, varscan2
- OR10AC1 | c.438C>T p.R146= | Silent (SNP) | VAF 679/683 reads (99%) | called by muse, mutect2, varscan2
- OR2M4 | c.147C>A p.I49= | Silent (SNP) | VAF 280/444 reads (63%) | catalogued as COSV60707477; called by muse, mutect2, varscan2
- PCARE | c.1131C>T p.P377= | Silent (SNP) | VAF 772/775 reads (100%) | catalogued as rs1236713028, COSV100527285, COSV100527772; called by muse, varscan2
- PCDHGC3 | c.1068C>T p.S356= | Silent (SNP) | VAF 202/432 reads (47%) | called by muse, mutect2, varscan2
- PDPK1 | c.1170G>A p.S390= | Silent (SNP) | VAF 134/381 reads (35%) | called by muse, mutect2, varscan2
- PPP1R32 | c.660G>A p.P220= | Silent (SNP) | VAF 268/442 reads (61%) | catalogued as rs367569481; called by muse, mutect2, varscan2
- PRDM13 | c.1221C>T p.R407= | Silent (SNP) | VAF 268/541 reads (50%) | catalogued as rs1373869715; called by muse, mutect2, varscan2
- PSAPL1 | c.870C>T p.A290= | Silent (SNP) | VAF 228/484 reads (47%) | catalogued as rs577743929, COSV100040690, COSV100040695; called by muse, mutect2, varscan2
- RBFOX1 | c.105C>T p.N35= | Silent (SNP) | VAF 366/574 reads (64%) | catalogued as rs542828240, COSV100300124; called by muse, varscan2
- RBM33 | c.1836G>A p.P612= | Silent (SNP) | VAF 72/246 reads (29%) | catalogued as rs749763123; called by muse, mutect2, varscan2
- RBMXL1 | c.783C>T p.G261= | Silent (SNP) | VAF 178/427 reads (42%) | catalogued as rs1407390478; called by muse, mutect2, varscan2
- SARDH | c.1161G>A p.T387= | Silent (SNP) | VAF 412/416 reads (99%) | catalogued as rs370661854; called by muse, mutect2, varscan2
- SCRT1 | c.93C>T p.L31= | Silent (SNP) | VAF 143/320 reads (45%) | called by muse, mutect2, varscan2
- SDHA | c.1233C>T p.G411= | Silent (SNP) | VAF 103/400 reads (26%) | catalogued as rs376530094; ClinVar: likely benign; called by muse, mutect2, varscan2
- SELENOV | c.465G>A p.P155= | Silent (SNP) | VAF 252/1357 reads (19%) | called by muse, mutect2, varscan2
- SESTD1 | c.1032C>T p.G344= | Silent (SNP) | VAF 341/341 reads (100%) | catalogued as rs747028596, COSV58931571; called by muse, mutect2, varscan2
- SHANK3 | c.4146C>T p.S1382= | Silent (SNP) | VAF 437/440 reads (99%) | catalogued as rs767710495; called by muse, mutect2, varscan2
- SHISA7 | c.1320C>T p.D440= | Silent (SNP) | VAF 298/914 reads (33%) | called by muse, mutect2, varscan2
- SLC36A1 | c.1062G>A p.P354= | Silent (SNP) | VAF 142/261 reads (54%) | catalogued as rs757212363; called by muse, mutect2, varscan2
- SLC6A18 | c.1857G>A p.T619= | Silent (SNP) | VAF 348/881 reads (40%) | catalogued as rs777309236, COSV57253936; called by muse, mutect2, varscan2
- SMARCA4 | c.4251C>T p.S1417= | Silent (SNP) | VAF 227/449 reads (51%) | catalogued as rs377057304; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- SOGA3 | c.2208C>T p.Y736= | Silent (SNP) | VAF 231/467 reads (49%) | catalogued as COSV64109382; called by muse, mutect2, varscan2
- SPOCK2 | c.1245C>T p.G415= | Silent (SNP) | VAF 491/495 reads (99%) | catalogued as rs369710370; called by muse, mutect2
- SPTBN2 | c.5445G>A p.A1815= | Silent (SNP) | VAF 281/840 reads (33%) | catalogued as rs781339625; called by muse, mutect2, varscan2
- ST8SIA5 | c.12G>A p.A4= | Silent (SNP) | VAF 125/278 reads (45%) | catalogued as COSV59332048; called by muse, mutect2, varscan2
- STRIP1 | c.2247C>T p.D749= | Silent (SNP) | VAF 94/238 reads (39%) | catalogued as rs370148796; called by muse, mutect2, varscan2
- STS | c.495C>T p.C165= | Silent (SNP) | VAF 16/416 reads (4%) | called by muse, mutect2
- TCHH | c.1191C>T p.R397= | Silent (SNP) | VAF 99/542 reads (18%) | called by muse, varscan2
- TCHH | c.1173C>T p.R391= | Silent (SNP) | VAF 186/558 reads (33%) | called by muse, varscan2
- TEAD2 | c.1140C>T p.C380= | Silent (SNP) | VAF 143/505 reads (28%) | catalogued as rs565615340, COSV60543433; called by muse, mutect2, varscan2
- TRIM67 | c.285C>T p.G95= | Silent (SNP) | VAF 576/874 reads (66%) | called by muse, varscan2
- TSHZ3 | c.1611C>A p.A537= | Silent (SNP) | VAF 182/517 reads (35%) | called by muse, mutect2, varscan2
- WDR7 | c.2526C>T p.G842= | Silent (SNP) | VAF 167/367 reads (46%) | called by muse, mutect2, varscan2
- WDR97 | c.1344C>T p.C448= | Silent (SNP) | VAF 306/602 reads (51%) | called by muse, mutect2, varscan2
- ZNF233 | c.717T>C p.C239= | Silent (SNP) | VAF 294/428 reads (69%) | called by muse, mutect2, varscan2
- ZNF729 | c.3669G>A p.K1223= | Silent (SNP) | VAF 123/220 reads (56%) | catalogued as rs1301116853; called by muse, mutect2, varscan2
- ZP2 | c.1317C>T p.N439= | Silent (SNP) | VAF 70/228 reads (31%) | catalogued as rs141585544; called by muse, mutect2, varscan2
- ZSCAN20 | c.2694G>A p.T898= | Silent (SNP) | VAF 167/324 reads (52%) | catalogued as rs375842451; called by muse, mutect2, varscan2
- C4orf50 | c.-853C>T | 5'UTR (SNP) | VAF 161/346 reads (47%) | catalogued as rs541992927; called by muse, mutect2, varscan2
- CD99 | c.475+962G>A | Intron (SNP) | VAF 194/196 reads (99%) | catalogued as rs768970892, COSV101152291; called by muse, mutect2, varscan2
- CDIN1 | c.716+37069C>A | Intron (SNP) | VAF 105/368 reads (29%) | called by muse, varscan2
- DNAH10 | c.13307-432C>T | Intron (SNP) | VAF 121/358 reads (34%) | catalogued as rs552839988; called by muse, mutect2, varscan2
- HYDIN | c.-10del | 5'UTR (DEL) | VAF 154/248 reads (62%) | catalogued as rs768899959; called by mutect2, varscan2
- KARS1 | c.63-2698C>T | Intron (SNP) | VAF 97/340 reads (29%) | catalogued as rs762578862, COSV55613883; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+22742A>G | Intron (SNP) | VAF 332/334 reads (99%) | called by muse, mutect2, varscan2
- NSUN4 | c.94-1721C>T | Intron (SNP) | VAF 128/281 reads (46%) | catalogued as rs1480831020, COSV61062673; called by muse, mutect2, varscan2
- OR11H6 | chr14:20229476 C>A | 3'Flank (SNP) | VAF 17/298 reads (6%) | catalogued as rs1021401057; called by muse, mutect2
- OR2S1P | n.273-9542C>T | Intron (SNP) | VAF 104/201 reads (52%) | catalogued as rs769108435; called by muse, mutect2, varscan2
- SYTL2 | c.1459+46G>A | Intron (SNP) | VAF 172/542 reads (32%) | catalogued as rs375253029; called by muse, mutect2, varscan2
- USH1C | c.1285-7514G>A | Intron (SNP) | VAF 216/317 reads (68%) | catalogued as rs756008323; called by muse, mutect2, varscan2
